MMRF case MMRF_2246 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1e65559f-9949-4c8b-bd90-50e75a237a90

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.5 years (23,938 days); ISS stage: III; Days to last known disease status: 773 days (2.1 years); Days to last follow up: 773 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 23 days; Days to treatment end: 219 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -32: M Protein 7.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 24.1 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 7.6 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.02 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 5.94 mmol/L.
- Day 70 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.94 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 4.51 mmol/L.
- Day 122 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 7.76 g/L; Immunoglobulin A 2.02 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 220: M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 9.84 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 5.06 mmol/L.
- Day 325: M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 9.13 g/L; Immunoglobulin A 2.3 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.08 ×10⁹/L; Absolute Neutrophil 3.97 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 3.58 mmol/L.
- Day 416: M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 8.85 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5.23 ×10⁹/L; Platelets 365 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.73 mmol/L.
- Day 520 (ECOG 1): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 9.6 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.32 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 625 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.35 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.12 mmol/L.
- Day 674: Hemoglobin 7.32 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Glucose 6.11 mmol/L.
- Day 773: M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 1.8 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.53 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -32: Weight: 85 kg; Height: 164 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2246_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -32 days.
- Sample MMRF_2246_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -32 days.
